FM case AD14930 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/db500b32-bbf3-4927-8b0d-1810b10950b2

Female, 38.3 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the bone. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Metastatic.
